Somatic mutation profile of tumor specimen TCGA-22-4599-01A (aliquot TCGA-22-4599-01A-01D-1441-08) from TCGA case TCGA-22-4599, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.7 years (26,925 days).
Specimen TCGA-22-4599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 058db961-bfe4-4b44-9111-269b17868ead.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4599-11A (Solid Tissue Normal), aliquot TCGA-22-4599-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63cfb8fa-af86-4143-afbb-574f0d89cdac

The open-access MAF lists 393 somatic variants for this specimen: 293 protein-altering or splice-affecting, 92 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 92, Nonsense Mutation 19, Frame Shift Del 8, Splice Site 7, Frame Shift Ins 5, RNA 4, Intron 2, In Frame Del 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 20/28 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50296596, COSV99408076; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.2477A>T p.D826V (on ENST00000302538 / NM_021962.5; = p.D789V on NM_001092.5) | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52147151; called by muse, varscan2
- ACCSL | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66581508; called by muse, mutect2, varscan2
- ADAMTS12 | c.3196C>A p.Q1066K | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV61265687; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58441682; called by muse, mutect2, varscan2
- ADGRV1 | c.16639C>T p.R5547C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1446694263, COSV67987576; called by muse, mutect2, varscan2
- AHNAK2 | c.10022A>T p.D3341V | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV60918375; called by muse, mutect2, varscan2
- AMPH | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57745073, COSV57748302; called by muse, mutect2, varscan2
- ANKLE2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs781042749, COSV61709899; called by muse, mutect2, varscan2
- ANKRD36B | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51533230; called by muse, mutect2, varscan2
- ANO1 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60285820; called by muse, mutect2, varscan2
- APOA5 | c.488dup p.V166Rfs*102 | Frame Shift Ins (INS) | VAF 55/159 reads (35%) | catalogued as COSV99911552; called by mutect2, pindel, varscan2
- APOB | c.9612T>A p.F3204L | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV51939423; called by muse, mutect2, varscan2
- ARHGAP31 | c.3454G>T p.A1152S | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV51794384; called by muse, mutect2
- ARMH4 | c.264A>T p.K88N | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV50765951; called by muse, mutect2, varscan2
- ASAP1 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV63049902; called by muse, mutect2, varscan2
- ASB10 | c.1393G>T p.V465L (on ENST00000420175 / NM_001142459.2; = p.V450L on NM_080871.4) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV51996767, COSV51996981; called by muse, mutect2, varscan2
- ASCC3 | c.3343G>C p.V1115L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs765295534, COSV61229809; called by muse, mutect2, varscan2
- ASTN2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as rs767177206, COSV57759117; called by muse, varscan2
- ASXL3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.967); catalogued as COSV52469165, COSV52480834; called by muse, mutect2, varscan2
- ATP2A3 | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs776418170, COSV59226250, COSV59230333; called by muse, mutect2, varscan2
- ATP9A | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58765920, COSV58767865; called by muse, mutect2, varscan2
- ATR | c.7226G>C p.C2409S | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.173); catalogued as COSV100637788, COSV63387451; called by muse, mutect2, varscan2
- ATR | c.3643G>T p.V1215L | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs1350034295, COSV63387455; called by muse, mutect2, varscan2
- BAG5 | c.334T>G p.F112V | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54571366; called by muse, mutect2, varscan2
- BTN2A2 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV61857708; called by muse, mutect2, varscan2
- C22orf42 | c.489C>A p.D163E | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.124); catalogued as rs759151242, COSV66076157; called by muse, mutect2, varscan2
- CACNA1A | c.5720G>A p.R1907H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64190845, COSV64196346; called by muse, mutect2, varscan2
- CBLB | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51429121; called by muse, varscan2
- CCDC138 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV54568183; called by muse, mutect2, varscan2
- CCDC38 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV60183454; called by muse, mutect2, varscan2
- CCNF | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs142982582; called by muse, mutect2, varscan2
- CCNT2 | c.1660A>G p.R554G | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs757139153, COSV51473924; called by muse, mutect2, varscan2
- CD163 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63133576; called by muse, mutect2, varscan2
- CD226 | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.294); catalogued as COSV54613326; called by muse, mutect2, varscan2
- CDH10 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52573112, COSV52584409; called by muse, mutect2, varscan2
- CDH20 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.734); catalogued as COSV53011666, COSV99406569; called by muse, mutect2, varscan2
- CENPJ | c.2215G>T p.G739W | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67883591; called by muse, mutect2, varscan2
- CHIA | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV58475963; called by muse, mutect2, varscan2
- CHRNA6 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs200592176, COSV52379909; called by muse, mutect2
- CLDN9 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60910971; called by muse, mutect2, varscan2
- CNGB3 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 78/344 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60691538; called by muse, mutect2, varscan2
- CNTN5 | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54319863; called by muse, mutect2, varscan2
- CNTN6 | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV63175765; called by muse, mutect2, varscan2
- CNTNAP5 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70473113; called by muse, mutect2
- COL22A1 | c.4178G>C p.G1393A | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342146; called by muse, mutect2, varscan2
- COL8A2 | c.978C>G p.D326E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV57442129; called by muse, mutect2, varscan2
- CPEB4 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 139/337 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV54173032; called by muse, mutect2, varscan2
- CPM | c.259-1G>C p.X87_splice | Splice Site (SNP) | VAF 59/98 reads (60%) | catalogued as COSV58033860; called by muse, mutect2, varscan2
- CRB1 | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.809); catalogued as COSV66331089, COSV66331219; called by muse, mutect2, varscan2
- CRB1 | c.3834G>T p.Q1278H | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66329386; called by muse, mutect2, varscan2
- CSHL1 | c.621C>G p.F207L (on ENST00000309894 / NM_022581.3; = p.F113L on NM_001318.4) | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51988701, COSV99368172; called by muse, mutect2, varscan2
- CSMD2 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs932600876, COSV53874885, COSV99588242; called by muse, mutect2, varscan2
- CSMD3 | c.9461A>T p.Q3154L (on ENST00000297405 / NM_001363185.1; = p.Q2985L on NM_052900.3) | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV52209244; called by muse, mutect2, varscan2
- CTNNA2 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.155); catalogued as COSV63575279; called by muse, mutect2, varscan2
- CYP2J2 | c.1331-1G>A p.X444_splice | Splice Site (SNP) | VAF 10/227 reads (4%) | catalogued as COSV100967966; called by muse, mutect2
- DDX46 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62799622; called by muse, mutect2
- DDX54 | c.2367C>A p.D789E | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58374305; called by muse, mutect2, varscan2
- DGKG | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53966627; called by muse, mutect2, varscan2
- DIDO1 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs943598507, COSV56625478; called by muse, mutect2, varscan2
- DLK1 | c.1093T>G p.F365V | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV57992024; called by muse, mutect2, varscan2
- DNM3 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 171/327 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs758244650, COSV62459511; called by muse, mutect2, varscan2
- DOCK10 | c.1505A>T p.H502L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51417754; called by muse, mutect2, varscan2
- DOCK10 | c.1504C>A p.H502N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1211323414, COSV51417764; called by muse, varscan2
- DPEP2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52054887, COSV52056208; called by muse, mutect2, varscan2
- DPP6 | c.989C>A p.T330N (on ENST00000377770 / NM_001364500.2; = p.T268N on NM_001936.5) | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.431); catalogued as rs750212774, COSV59620852; called by muse, mutect2, varscan2
- DPP6 | c.2085G>T p.M695I (on ENST00000377770 / NM_001364500.2; = p.M633I on NM_001936.5) | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV59620877; called by muse, mutect2, varscan2
- DPY19L2 | c.1932G>C p.M644I | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61042827; called by muse, varscan2
- DUSP29 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 40/83 reads (48%) | catalogued as COSV58300803; called by muse, mutect2, varscan2
- DVL3 | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57456650; called by muse, mutect2, varscan2
- ECM2 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 127/504 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV60741385; called by muse, mutect2, varscan2
- EGF | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54480116; called by muse, mutect2, varscan2
- EIF3E | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55203571; called by muse, mutect2, varscan2
- EPHA7 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV65184881; called by muse, mutect2, varscan2
- EPHB1 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.142); catalogued as COSV67663308, COSV67663778; called by muse, mutect2, varscan2
- F13B | c.407T>A p.L136H | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV66374315; called by muse, mutect2, varscan2
- F13B | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs757094432, CM103616, COSV66374321, COSV66374405; called by muse, mutect2, varscan2
- F9 | c.433T>A p.C145S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM940502, COSV54380862; called by muse, mutect2, varscan2
- FADS6 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.036); catalogued as COSV59602841; called by muse, mutect2, varscan2
- FAM47B | c.1415T>G p.L472R | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV61454574; called by muse, mutect2, varscan2
- FANCF | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); catalogued as COSV59416476; called by muse, mutect2, varscan2
- FCGR2B | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52681975, COSV99374996; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58556892; called by muse, mutect2, varscan2
- FRRS1 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 74/151 reads (49%) | catalogued as COSV54922682, COSV54923944; called by muse, mutect2, varscan2
- GABBR1 | c.1260G>T p.E420D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63543016; called by muse, mutect2, varscan2
- GABRG3 | c.162G>C p.L54F | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61510598, COSV61520915; called by muse, mutect2, varscan2
- GLI2 | c.3194C>G p.T1065S (on ENST00000361492 / NM_001374353.1; = p.T1082S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.051); catalogued as COSV58044120; called by muse, mutect2, varscan2
- GRIA3 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52047938; called by muse, mutect2, varscan2
- GRID1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60025527, COSV60034101; called by muse, mutect2, varscan2
- GSE1 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV53672921; called by muse, mutect2
- H2AC4 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs376552436, COSV52519018; called by muse, mutect2
- H2AZ2 | c.214A>G p.N72D | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV56062587; called by muse, mutect2, varscan2
- HAO1 | c.814-1G>T p.X272_splice | Splice Site (SNP) | VAF 57/266 reads (21%) | catalogued as CS147006, COSV66492376; called by muse, mutect2, varscan2
- HERC2 | c.10975G>A p.D3659N | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55328564; called by muse, mutect2, varscan2
- HFM1 | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV54029458; called by muse, mutect2, varscan2
- HSD3B1 | c.277C>A p.H93N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV52491073; called by muse, mutect2, varscan2
- ICA1 | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55580070; called by muse, mutect2, varscan2
- ICE1 | c.6316G>C p.G2106R | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56822571, COSV56827026; called by muse, mutect2, varscan2
- IFNA14 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.204); catalogued as COSV66516203; called by muse, mutect2, varscan2
- IGSF1 | c.3742G>T p.G1248W | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63838123; called by muse, mutect2, varscan2
- IL7R | c.876A>T p.K292N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.94); catalogued as COSV57409413; called by muse, mutect2, varscan2
- INTS1 | c.5870A>C p.N1957T | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV67177922; called by muse, mutect2, varscan2
- ITGA8 | c.2982+2T>A p.X994_splice | Splice Site (SNP) | VAF 52/138 reads (38%) | catalogued as CS140875, COSV65230275; called by muse, mutect2, varscan2
- ITGA8 | c.891T>C p.Y297= | Splice Region (SNP) | VAF 37/104 reads (36%) | catalogued as COSV65230281; called by muse, mutect2, varscan2
- KBTBD3 | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | catalogued as COSV73241465; called by muse, mutect2, varscan2
- KCNA1 | c.876G>T p.R292S | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66837758; called by muse, mutect2, varscan2
- KCND2 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV58584725; called by muse, mutect2, varscan2
- KCNJ3 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.317); catalogued as COSV54537990; called by muse, mutect2, varscan2
- KCNS3 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58407416; called by muse, mutect2, varscan2
- KCNT2 | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV54085442; called by muse, mutect2
- KIAA1109 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV52677693; called by muse, mutect2, varscan2
- KIF1B | c.4699G>A p.D1567N (on ENST00000377086 / NM_001365952.1; = p.D1521N on NM_015074.3) | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV55810372; called by muse, mutect2, varscan2
- KRT12 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52430161; called by muse, mutect2, varscan2
- KRTAP6-1 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | PolyPhen benign (0.003); catalogued as COSV58168497; called by muse, mutect2, varscan2
- LAMA1 | c.7585G>A p.G2529R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs373829095; called by muse, mutect2, varscan2
- LELP1 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 155/311 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV64202512; called by muse, mutect2, varscan2
- LIFR | c.2230T>A p.W744R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54692101; called by muse, mutect2, varscan2
- LIG4 | c.1067A>T p.E356V | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV63597289; called by muse, mutect2, varscan2
- LMO7 | c.3130A>G p.I1044V (on ENST00000357063; = p.I725V on NM_005358.5) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58539274; called by muse, mutect2, varscan2
- LPAR4 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.995); catalogued as COSV70912787; called by muse, mutect2, varscan2
- LRFN5 | c.1841C>A p.S614* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV53260991; called by muse, mutect2, varscan2
- LRP1B | c.10900G>T p.E3634* | Nonsense Mutation (SNP) | VAF 37/165 reads (22%) | catalogued as COSV67233653; called by muse, mutect2, varscan2
- LRP1B | c.10817G>C p.C3606S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67233658; called by muse, mutect2, varscan2
- LRP1B | c.3213G>C p.W1071C | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67233664; called by muse, mutect2, varscan2
- LRP3 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV53504726; called by muse, varscan2
- LRRTM4 | c.1301T>A p.L434H | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV69140627; called by muse, mutect2, varscan2
- LVRN | c.1995A>T p.L665F | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV63497476; called by muse, mutect2, varscan2
- MCF2 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 182/364 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV58487076; called by muse, mutect2, varscan2
- MCM8 | c.1787C>A p.T596N | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV54515019; called by muse, mutect2, varscan2
- MDGA2 | c.2023T>G p.Y675D (on ENST00000399232 / NM_001113498.2; = p.Y377D on NM_182830.4) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.419); catalogued as rs1378732710, COSV62097243; called by muse, mutect2, varscan2
- MMP9 | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812377; called by muse, mutect2, varscan2
- MORC1 | c.2046G>A p.W682* | Nonsense Mutation (SNP) | VAF 354/886 reads (40%) | catalogued as COSV51722093, COSV51732092; called by mutect2, varscan2
- MPHOSPH9 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV56620776; called by muse, mutect2, varscan2
- MPZL3 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54053454; called by muse, mutect2
- MRRF | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52914839; called by muse, mutect2, varscan2
- MYH7 | c.5078A>G p.E1693G | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62520411; called by muse, mutect2, varscan2
- MYO9B | c.4526A>G p.N1509S | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs754380541, COSV68279950; called by muse, mutect2, varscan2
- NCAN | c.1637A>G p.N546S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV53052713; called by muse, mutect2, varscan2
- NCOA1 | c.1800C>G p.N600K | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV56046358; called by muse, mutect2, varscan2
- NCOA1 | c.3751C>A p.P1251T | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56046377; called by muse, mutect2, varscan2
- NEXMIF | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50039967, COSV50051719; called by muse, mutect2, varscan2
- NEXMIF | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV50040052; called by muse, mutect2, varscan2
- NFIC | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59413423; called by muse, mutect2, varscan2
- NMU | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 76/188 reads (40%) | catalogued as COSV51700361; called by muse, mutect2, varscan2
- NR3C2 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.837); catalogued as rs1471274661, COSV60992972; called by muse, mutect2, varscan2
- NRK | c.1790A>G p.H597R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV54598764; called by muse, mutect2, varscan2
- NSMF | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1369183266, COSV53000399; called by muse, mutect2, varscan2
- NSUN4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1323455383, COSV61063335; called by muse, mutect2, varscan2
- NUCB2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV60375643; called by muse, mutect2, varscan2
- OR10C1 | c.185del p.F62Sfs*76 (on ENST00000622521; = p.F60Sfs*76 on NM_013941.3) | Frame Shift Del (DEL) | VAF 59/148 reads (40%) | catalogued as COSV65822234; called by mutect2, pindel, varscan2
- OR10H2 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59946218; called by muse, mutect2, varscan2
- OR11L1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV63314781; called by muse, mutect2, varscan2
- OR11L1 | c.152A>C p.Q51P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV63314784; called by muse, mutect2, varscan2
- OR2G6 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58574862; called by muse, mutect2, varscan2
- OR2T8 | c.803A>T p.H268L | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs935433333, COSV60662972; called by muse, mutect2, varscan2
- OR4B1 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV58883108; called by muse, mutect2, varscan2
- OR4C11 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1204195525, COSV56352242, COSV56353754; called by muse, mutect2, varscan2
- OR4S2 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 119/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56747278; called by muse, mutect2, varscan2
- OR51B2 | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as rs764726412, COSV100173330; called by muse, mutect2, varscan2
- OR51G1 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV58968358; called by muse, mutect2, varscan2
- OR51G1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV58969577; called by muse, mutect2, varscan2
- OR56A4 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58110508; called by muse, mutect2, varscan2
- OR5K4 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 78/484 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV61583871; called by muse, mutect2, varscan2
- OR5T3 | c.908G>C p.S303T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV57381159; called by muse, mutect2
- OR6Y1 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.094); catalogued as rs1214452867, COSV56928937, COSV56929781; called by muse, mutect2
- OR8B2 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66664880; called by muse, mutect2, varscan2
- OR8G5 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100422319; called by muse, mutect2, varscan2
- OR8I2 | c.467C>A p.S156* | Nonsense Mutation (SNP) | VAF 44/214 reads (21%) | catalogued as COSV56168001, COSV56168420; called by muse, varscan2
- OSTM1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs927664441, COSV51970300; called by muse, mutect2, varscan2
- OTOGL | c.4629C>G p.S1543R (on ENST00000547103; = p.S1534R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.625); catalogued as COSV100086954; called by muse, mutect2, varscan2
- PAPPA2 | c.2198A>G p.H733R | Missense Mutation (SNP) | VAF 175/348 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62779961; called by muse, mutect2, varscan2
- PAPPA2 | c.3272T>A p.V1091D | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62800246; called by muse, mutect2, varscan2
- PCDH11X | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 85/167 reads (51%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.823); catalogued as COSV53474910; called by muse, mutect2, varscan2
- PCDH11X | c.3637C>A p.P1213T | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53474947; called by muse, mutect2, varscan2
- PCDHB5 | c.237A>G p.I79M | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV50655072; called by muse, mutect2, varscan2
- PCDHGA1 | c.1531A>C p.T511P | Missense Mutation (SNP) | VAF 121/246 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV65297131; called by muse, mutect2, varscan2
- PCLO | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV61641559; called by muse, mutect2, varscan2
- PCNT | c.7102C>T p.P2368S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV64029457; called by muse, mutect2, varscan2
- PHACTR1 | c.647A>T p.D216V | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV60669997; called by muse, mutect2, varscan2
- PKD2L1 | c.1789C>A p.L597M | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs752343551, COSV58396550, COSV58397992; called by muse, mutect2, varscan2
- PKHD1L1 | c.2860G>C p.V954L | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV65745305; called by muse, mutect2, varscan2
- PKP4 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as rs1188607276, COSV67677702; called by muse, mutect2
- PLEKHH2 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56756032; called by muse, mutect2, varscan2
- PLPPR4 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 50/104 reads (48%) | catalogued as COSV64566327; called by muse, mutect2, varscan2
- PNOC | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs372130597; called by muse, mutect2, varscan2
- PNOC | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs533728896, COSV57283547; called by muse, mutect2, varscan2
- POLR1F | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.322); catalogued as COSV55998747; called by muse, mutect2, varscan2
- PPP1R13L | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as rs1453439689, COSV62908763; called by muse, mutect2, varscan2
- PREX2 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.298); catalogued as COSV55777297; called by muse, mutect2, varscan2
- PRKG1 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV64872543; called by muse, mutect2, varscan2
- PRMT2 | c.328-1G>T p.X110_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52455801, COSV52456375; called by muse, mutect2
- PRSS35 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV63800729; called by muse, mutect2, varscan2
- PSEN2 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV60916703; called by muse, mutect2, varscan2
- PYHIN1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV63722790; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51483806; called by muse, mutect2, varscan2
- RAG2 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.357); catalogued as COSV57558084, COSV57558103, COSV57558169; called by muse, mutect2, varscan2
- RALYL | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV72821929; called by muse, mutect2, varscan2
- RP1L1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV66756369; called by muse, mutect2, varscan2
- RPS6KA6 | c.1003T>G p.W335G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53121212; called by muse, mutect2, varscan2
- RSF1 | c.2813G>T p.C938F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841054; called by muse, mutect2, varscan2
- RTP3 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56123990; called by muse, mutect2, varscan2
- RYR2 | c.1047G>C p.M349I | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV63691211; called by muse, mutect2, varscan2
- RYR2 | c.7199G>T p.G2400V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM133737, COSV63691216; called by muse, mutect2, varscan2
- RYR2 | c.10158G>C p.K3386N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV63659149, COSV63691221; called by muse, mutect2, varscan2
- S100PBP | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1367100772, COSV63140213; called by muse, mutect2, varscan2
- SAMD13 | c.176A>G p.Y59C (on ENST00000370671; = p.Y53C on NM_001010971.3) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65745079; called by muse, mutect2, varscan2
- SEMA6C | c.1886G>C p.C629S | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59004286; called by muse, mutect2, varscan2
- SIAH3 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV68552183; called by muse, mutect2, varscan2
- SIRPA | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV61539389; called by muse, mutect2, varscan2
- SLC18A1 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs767773615, COSV52348750; called by muse, mutect2, varscan2
- SLC24A4 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV100103901, COSV54114812; called by muse, mutect2, varscan2
- SLC26A3 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV60640766; called by muse, mutect2, varscan2
- SLC37A3 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58265789; called by muse, mutect2, varscan2
- SLC46A2 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs771707629, COSV65290096; called by muse, mutect2
- SLC8A1 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60484424, COSV60487531; called by muse, mutect2
- SLC8A2 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52640366; called by muse, mutect2
- SMS | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV65114505; called by muse, mutect2, varscan2
- SNTG1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52449973; called by muse, varscan2
- SOX6 | c.1966G>T p.G656* (on ENST00000528429 / NM_001145819.2; = p.G629* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 44/202 reads (22%) | catalogued as COSV57048809; called by muse, mutect2, varscan2
- SPTA1 | c.6350G>T p.S2117I | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63754822; called by muse, mutect2, varscan2
- SPTA1 | c.4860G>T p.E1620D | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV63754824; called by muse, mutect2, varscan2
- SPTA1 | c.4580C>A p.S1527Y | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63754827; called by muse, mutect2, varscan2
- SPTB | c.968C>A p.T323N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV67632654; called by muse, mutect2, varscan2
- STC2 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); catalogued as COSV54180326; called by muse, mutect2, varscan2
- STK33 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV59403181; called by muse, mutect2, varscan2
- STKLD1 | c.1856T>C p.V619A | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554778424, COSV64241811; called by muse, mutect2, varscan2
- SUPT5H | c.2759G>A p.G920D | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV63240241; called by muse, mutect2, varscan2
- SUSD2 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV54083464, COSV54084330; called by muse, mutect2, varscan2
- TASP1 | c.1045T>A p.C349S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as COSV61813608; called by muse, mutect2, varscan2
- TBC1D32 | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51545548; called by muse, mutect2, varscan2
- TBC1D4 | c.1427C>A p.A476D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66489729; called by muse, mutect2, varscan2
- TECRL | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67087784; called by muse, mutect2, varscan2
- TECTA | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs1313344538, COSV99879210; called by muse, mutect2, varscan2
- TENM4 | c.6821C>T p.A2274V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53637354; called by muse, mutect2, varscan2
- TEX47 | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV51879235; called by muse, mutect2, varscan2
- TKTL2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs372750871; called by muse, mutect2, varscan2
- TMEM184A | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52474029, COSV99868751; called by muse, mutect2, varscan2
- TMEM200C | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV67309629; called by muse, mutect2, varscan2
- TMEM71 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as COSV63457836; called by muse, mutect2, varscan2
- TNS3 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748135582, COSV60792807; called by muse, mutect2, varscan2
- TOGARAM2 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV65421111, COSV65422079; called by muse, mutect2, varscan2
- TRANK1 | c.4593G>T p.Q1531H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57153379; called by muse, mutect2, varscan2
- TRAT1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55469135; called by muse, mutect2, varscan2
- TRIB3 | c.74T>C p.L25S | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV53931674; called by muse, mutect2, varscan2
- TRIM55 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV52547091; called by muse, mutect2, varscan2
- TRIM58 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63570748; called by muse, mutect2, varscan2
- TRIOBP | c.3776G>C p.G1259A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100730854, COSV60379224; called by muse, mutect2, varscan2
- TTN | c.39125G>C p.S13042T (on ENST00000591111; = p.S5618T on NM_003319.4) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | PolyPhen probably damaging (0.991); catalogued as COSV60128076; called by muse, mutect2, varscan2
- USH2A | c.6209C>A p.S2070Y | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1343610726, COSV56384392; called by muse, mutect2, varscan2
- USP7 | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as COSV61215316; called by muse, mutect2, varscan2
- VN1R1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV58091224; called by muse, mutect2, varscan2
- VPS41 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56070620; called by muse, mutect2, varscan2
- VSTM4 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 47/105 reads (45%) | catalogued as COSV60524685, COSV60527240; called by muse, mutect2, varscan2
- WAPL | c.3560T>G p.L1187W | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53936381; called by muse, mutect2, varscan2
- WDR6 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58244656; called by muse, mutect2, varscan2
- WNT3 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV56645740; called by muse, mutect2, varscan2
- ZBTB49 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61925276; called by muse, mutect2, varscan2
- ZDHHC8 | c.2143A>T p.K715* | Nonsense Mutation (SNP) | VAF 63/376 reads (17%) | catalogued as COSV100273240, COSV57711006; called by muse, mutect2, varscan2
- ZFAND4 | c.261-2A>G p.X87_splice | Splice Site (SNP) | VAF 47/79 reads (59%) | catalogued as COSV58897558; called by muse, mutect2, varscan2
- ZFHX4 | c.8194T>A p.Y2732N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.421); catalogued as COSV51438210; called by muse, mutect2, varscan2
- ZFHX4 | c.8729del p.P2910Qfs*27 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as COSV50641431; called by mutect2, pindel, varscan2
- ZFHX4 | c.9299G>T p.G3100V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51438293; called by muse, mutect2, varscan2
- ZIC1 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51554616; called by muse, varscan2
- ZIC1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51554633; called by muse, varscan2
- ZIC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 156/429 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV67172347; called by muse, mutect2, varscan2
- ZNF16 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52763435; called by muse, mutect2, varscan2
- ZNF208 | c.2649T>A p.H883Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV68107815, COSV68110399; called by muse, mutect2, varscan2
- ZNF208 | c.2420G>C p.C807S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68107829; called by muse, mutect2, varscan2
- ZNF354B | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV59366509; called by muse, mutect2, varscan2
- ZNF470 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57969292; called by muse, mutect2, varscan2
- ZNF479 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 46/188 reads (24%) | catalogued as COSV58637132, COSV58642676; called by muse, mutect2, varscan2
- ZNF521 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.898); catalogued as rs555923496, COSV64128093, COSV64128576; called by muse, mutect2, varscan2
- ZNF831 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs781462631, COSV100925748, COSV64041481; called by muse, mutect2, varscan2
- ZNF98 | c.1697G>T p.R566I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1167328234, COSV63334609, COSV63335429; called by muse, mutect2, varscan2
- ZSCAN31 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60181110; called by muse, mutect2, varscan2
- ADAMTS8 | c.1322dup p.R442Pfs*39 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- ALPK2 | c.4301del p.G1434Vfs*29 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | called by mutect2, pindel, varscan2
- ANGPTL4 | c.783_788del p.K261_H263delinsN | In Frame Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel, varscan2
- EEF2 | c.1398_1399del p.C466Wfs*50 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by pindel, varscan2
- HCRTR2 | c.1106-12_1125del p.X369_splice | Splice Site (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel
- HSPA6 | c.1272del p.K425Sfs*27 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | called by mutect2, varscan2
- ITGAX | c.276_306del p.G93Pfs*53 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel
- MAGEB3 | c.732dup p.R245Qfs*12 | Frame Shift Ins (INS) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- NYNRIN | c.3740dup p.R1248Pfs*56 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- OR11H6 | c.895dup p.M299Nfs*11 | Frame Shift Ins (INS) | VAF 38/249 reads (15%) | called by mutect2, pindel, varscan2
- PTEN | c.981del p.A328Qfs*16 | Frame Shift Del (DEL) | VAF 85/227 reads (37%) | called by mutect2, pindel, varscan2
- RBP3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- RGS22 | c.704del p.P235Qfs*30 | Frame Shift Del (DEL) | VAF 52/158 reads (33%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1828C>G p.H610D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- TDRD7 | c.1578_1580del p.E526del | In Frame Del (DEL) | VAF 15/95 reads (16%) | called by pindel, varscan2
- TPTE | c.1123G>C p.D375H (on ENST00000618007 / NM_199261.4; = p.D357H on NM_199259.4) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2
- AC098582.1 | c.6A>G p.L2= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV52021209; called by muse, mutect2, varscan2
- ACSM2A | c.1599A>G p.S533= (on ENST00000219054; = p.S454= on NM_001308169.2) | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as COSV54585874; called by muse, mutect2, varscan2
- ADAD1 | c.765C>T p.Y255= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV56644293; called by muse, mutect2, varscan2
- ADGRA1 | c.420A>G p.A140= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV74142849; called by muse, mutect2, varscan2
- ALK | c.1053G>T p.V351= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as COSV66572527; called by muse, mutect2, varscan2
- ALPI | c.627C>A p.L209= | Silent (SNP) | VAF 59/244 reads (24%) | catalogued as COSV55015004; called by muse, mutect2, varscan2
- ANO7 | c.945C>T p.V315= (on ENST00000274979; = p.V261= on NM_001370694.2) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV51473173; called by muse, mutect2, varscan2
- AQP8 | c.234C>A p.L78= | Silent (SNP) | VAF 96/171 reads (56%) | catalogued as COSV54845771; called by muse, mutect2, varscan2
- ATP10B | c.1408C>T p.L470= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as COSV58779166; called by muse, mutect2, varscan2
- BUB1 | c.573A>T p.S191= | Silent (SNP) | VAF 87/283 reads (31%) | catalogued as COSV57064422; called by muse, mutect2, varscan2
- CABP1 | c.741C>T p.C247= (on ENST00000316803 / NM_001033677.1; = p.C44= on NM_004276.5) | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV56458973; called by muse, mutect2, varscan2
- CASS4 | c.948A>T p.V316= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV64386822; called by muse, mutect2, varscan2
- CASS4 | c.1740C>T p.V580= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV64386826; called by muse, mutect2, varscan2
- CDKL1 | c.843G>A p.Q281= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV53580142; called by muse, mutect2, varscan2
- CFAP65 | c.336C>A p.A112= (on ENST00000341552 / NM_194302.4; = p.A47= on NM_152389.4) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV55390663; called by muse, mutect2, varscan2
- CNNM2 | c.513C>T p.G171= | Silent (SNP) | VAF 107/266 reads (40%) | catalogued as COSV63996099; called by muse, mutect2, varscan2
- COBL | c.1212C>T p.T404= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs758909898, COSV54348587, COSV54362292; called by muse, mutect2
- COLGALT2 | c.588G>C p.R196= | Silent (SNP) | VAF 50/419 reads (12%) | catalogued as COSV62729350; called by muse, mutect2, varscan2
- CRHBP | c.219C>T p.T73= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV57188914, COSV99169534; called by muse, mutect2, varscan2
- CSMD3 | c.9822A>G p.V3274= (on ENST00000297405 / NM_001363185.1; = p.V3105= on NM_052900.3) | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV52209229; called by muse, mutect2
- CTNNA2 | c.873C>G p.P291= | Silent (SNP) | VAF 58/197 reads (29%) | catalogued as COSV63575286; called by muse, mutect2, varscan2
- CXCR2 | c.897C>A p.T299= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV100579177, COSV59279855; called by muse, mutect2, varscan2
- CYLC2 | c.81A>G p.S27= | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as rs765725715, COSV66337964; called by muse, mutect2, varscan2
- DBR1 | c.168C>T p.P56= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53430210; called by muse, mutect2
- DCSTAMP | c.1270C>T p.L424= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV52578254, COSV52579806; called by muse, mutect2, varscan2
- DLK1 | c.1092C>A p.I364= | Silent (SNP) | VAF 52/238 reads (22%) | catalogued as COSV57992010; called by muse, mutect2, varscan2
- DNAH7 | c.9108A>T p.L3036= | Silent (SNP) | VAF 67/177 reads (38%) | catalogued as COSV56769424; called by muse, mutect2, varscan2
- DYSF | c.543G>T p.G181= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV50450768, COSV50460560; called by muse, mutect2, varscan2
- ENTPD6 | c.546A>T p.T182= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as COSV61751751; called by muse, mutect2, varscan2
- ETV4 | c.525T>C p.H175= | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as rs367792700; called by muse, mutect2, varscan2
- FAT3 | c.1806G>A p.A602= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1410181836, COSV53096647; called by muse, mutect2, varscan2
- FRMPD1 | c.1944C>T p.S648= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs760491862, COSV66700742; called by muse, mutect2, varscan2
- GABRG1 | c.730C>A p.R244= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV54956004; called by muse, mutect2, varscan2
- GRIN3B | c.1134G>A p.R378= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52260987; called by muse, varscan2
- H2AC4 | c.33T>G p.A11= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV52519027; called by muse, mutect2
- HACD1 | c.771A>G p.A257= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV63516559; called by muse, mutect2, varscan2
- HECW2 | c.1746A>T p.T582= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV53662645; called by muse, mutect2, varscan2
- HGD | c.993T>G p.P331= | Silent (SNP) | VAF 114/305 reads (37%) | catalogued as COSV52198904, COSV52199754; called by muse, mutect2, varscan2
- HMGCL | c.177G>T p.L59= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as COSV52526354; called by muse, mutect2, varscan2
- HYAL4 | c.1434C>T p.S478= | Silent (SNP) | VAF 89/258 reads (34%) | catalogued as rs1452974348, COSV56138937; called by muse, mutect2, varscan2
- IFIH1 | c.174A>G p.A58= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV55127521; called by muse, mutect2, varscan2
- ISL1 | c.390A>T p.R130= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV57934175; called by muse, mutect2, varscan2
- KCNA4 | c.267G>T p.R89= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV60253326; called by muse, mutect2, varscan2
- KDF1 | c.897C>T p.R299= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs142079202; called by muse, mutect2, varscan2
- KIF17 | c.939G>A p.S313= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs747253875, COSV56119162; called by muse, mutect2, varscan2
- KMT5C | c.57C>A p.T19= | Silent (SNP) | VAF 107/234 reads (46%) | catalogued as COSV55319443; called by muse, mutect2, varscan2
- KRTAP13-4 | c.147G>A p.R49= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV61878890, COSV61879413; called by muse, mutect2, varscan2
- MAB21L1 | c.378C>T p.R126= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV59792963; called by muse, mutect2, varscan2
- MAPK15 | c.996G>A p.V332= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV62028737; called by mutect2, varscan2
- MICAL2 | c.4440T>A p.G1480= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV56286657; called by muse, mutect2, varscan2
- MMP26 | c.546T>A p.P182= | Silent (SNP) | VAF 111/273 reads (41%) | catalogued as COSV56172653; called by muse, mutect2, varscan2
- MMP8 | c.24A>G p.P8= | Silent (SNP) | VAF 198/411 reads (48%) | catalogued as rs1033806397, COSV52633117, COSV99368636; called by muse, mutect2, varscan2
- MYH4 | c.1038T>C p.A346= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as COSV55120012; called by muse, mutect2, varscan2
- NEXMIF | c.1608C>G p.P536= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV50039844; called by muse, mutect2, varscan2
- NHS | c.3780C>T p.R1260= | Silent (SNP) | VAF 70/140 reads (50%) | catalogued as COSV66276969; called by muse, mutect2, varscan2
- NIBAN1 | c.349C>A p.R117= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV62282875, COSV62285431; called by muse, mutect2, varscan2
- NLRP11 | c.1440G>A p.E480= | Silent (SNP) | VAF 114/278 reads (41%) | catalogued as COSV64087816; called by muse, mutect2, varscan2
- OR4C6 | c.810T>A p.A270= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV58604553; called by muse, mutect2, varscan2
- OR4S2 | c.774C>A p.R258= | Silent (SNP) | VAF 120/272 reads (44%) | catalogued as rs780691729, COSV56747274; called by muse, mutect2, varscan2
- OR51T1 | c.777C>T p.S259= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV59026041; called by muse, mutect2, varscan2
- OR8B2 | c.639C>A p.T213= | Silent (SNP) | VAF 85/340 reads (25%) | catalogued as COSV66664876; called by muse, mutect2, varscan2
- OR8G5 | c.630C>G p.P210= | Silent (SNP) | VAF 83/346 reads (24%) | catalogued as rs1211851943, COSV100422321; called by muse, mutect2, varscan2
- PCDHGB1 | c.1950C>G p.L650= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV53966635; called by muse, mutect2
- PPM1E | c.69C>A p.R23= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV57575649; called by muse, mutect2, varscan2
- PPP1R3A | c.1542T>C p.G514= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV52884831; called by muse, mutect2, varscan2
- PREX1 | c.1632C>T p.P544= | Silent (SNP) | VAF 32/237 reads (14%) | catalogued as rs373526526; called by muse, mutect2, varscan2
- PSMB7 | c.15G>T p.S5= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99412734; called by muse, mutect2, varscan2
- PTPN4 | c.2403C>T p.N801= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV55303074; called by muse, varscan2
- PTPRF | c.3027G>T p.P1009= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV63445901; called by muse, mutect2, varscan2
- PZP | c.2556T>C p.Y852= | Silent (SNP) | VAF 110/308 reads (36%) | catalogued as rs757509523, COSV54362822; called by muse, mutect2, varscan2
- RAD9A | c.198T>G p.P66= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV57237199; called by muse, mutect2, varscan2
- RANBP9 | c.1926T>A p.T642= | Silent (SNP) | VAF 108/228 reads (47%) | catalogued as COSV50582031; called by muse, mutect2, varscan2
- RGS7 | c.1323C>A p.S441= | Silent (SNP) | VAF 92/329 reads (28%) | catalogued as COSV100469242, COSV58545346; called by muse, mutect2, varscan2
- RYR2 | c.606C>T p.H202= | Silent (SNP) | VAF 51/222 reads (23%) | catalogued as rs1438256315, COSV63691206; called by muse, mutect2, varscan2
- S100A3 | c.33C>T p.A11= | Silent (SNP) | VAF 227/464 reads (49%) | catalogued as COSV62876805; called by muse, mutect2, varscan2
- SCN1A | c.3588G>T p.V1196= (on ENST00000303395 / NM_001202435.3; = p.V1185= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as COSV57673851; called by muse, mutect2, varscan2
- SDS | c.774C>T p.F258= | Silent (SNP) | VAF 93/162 reads (57%) | catalogued as COSV55107249; called by muse, mutect2, varscan2
- SLC10A5 | c.345T>A p.I115= | Silent (SNP) | VAF 71/189 reads (38%) | catalogued as COSV72828396; called by muse, mutect2, varscan2
- SPDL1 | c.309A>T p.G103= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs1424027073, COSV54668506; called by muse, mutect2, varscan2
- SRARP | c.375C>T p.S125= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV61497835; called by muse, mutect2, varscan2
- TENM1 | c.5604T>C p.S1868= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV64434448; called by muse, mutect2, varscan2
- TMEM211 | c.519C>T p.P173= (on ENST00000423535; = p.P102= on NM_001001663.3) | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV66954161; called by muse, mutect2, varscan2
- TNKS | c.2676C>T p.Y892= | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as COSV60060050; called by muse, mutect2, varscan2
- TRAV12-2 | c.27G>T p.V9= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- TRPC6 | c.1206A>T p.T402= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV60256258; called by muse, mutect2, varscan2
- USP13 | c.690G>T p.L230= | Silent (SNP) | VAF 123/333 reads (37%) | catalogued as COSV55866697; called by muse, mutect2, varscan2
- VCAN | c.1686T>C p.L562= | Silent (SNP) | VAF 10/189 reads (5%) | catalogued as COSV54107609; called by muse, mutect2
- WDR64 | c.1935A>G p.L645= | Silent (SNP) | VAF 79/196 reads (40%) | catalogued as COSV63796860; called by muse, mutect2, varscan2
- ZIC3 | c.768C>A p.I256= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV54974864; called by muse, mutect2, varscan2
- ZNF133 | c.1098G>A p.R366= (on ENST00000316358 / NM_001352454.2; = p.R365= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV60367284; called by muse, mutect2, varscan2
- ZNF614 | c.168A>G p.V56= | Silent (SNP) | VAF 89/202 reads (44%) | catalogued as COSV54546752; called by muse, mutect2, varscan2
- ZNF827 | c.822G>T p.P274= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV65228296; called by muse, mutect2, varscan2
- AC005863.1 | n.359G>C | RNA (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- LINC01588 | n.41G>A | RNA (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1240G>T | RNA (SNP) | VAF 48/96 reads (50%) | catalogued as COSV59421200; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2949T>C | RNA (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23922T>A | Intron (SNP) | VAF 124/318 reads (39%) | catalogued as COSV67445204; called by muse, mutect2, varscan2
- SMS | c.*2G>T | 3'UTR (SNP) | VAF 39/87 reads (45%) | catalogued as COSV101047992; called by muse, mutect2, varscan2
- STARD8 | c.-38G>A | 5'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs763553473, COSV99366500; called by muse, mutect2, varscan2
- TTN | c.10360+2273A>C | Intron (SNP) | VAF 51/221 reads (23%) | catalogued as COSV60128107; called by muse, mutect2, varscan2
